Gene-level copy-number profile of tumor specimen TCGA-BS-A0TG-01A from TCGA case TCGA-BS-A0TG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 60.4 years (22,043 days).
Specimen TCGA-BS-A0TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b6d7ce8b-701a-4b75-aea8-db61ef72168d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BS-A0TG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ceaa24b6-773f-478a-96f8-a6e16263577b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 57,278; copy number 3: 2,505; copy number 4: 14; copy number 5: 14; copy number 6: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BS-A0TG-01A-32D-A102-01): tumor purity 0.74, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:172,138,397–172,144,840, 4 genes, copy number 6: DNM3OS, MIR214, MIR3120, MIR199A2.
- chr4:64,914,281–65,024,485, 1 gene, copy number 5 (within-gene range 2–5): LINC02232.
- chr4:79,596,542–79,597,173, 1 gene, copy number 5: AC092542.1.
- chr4:113,900,284–113,979,727, 2 genes, copy number 6 (within-gene range 2–6): ARSJ, AC104779.1.
- chr5:53,297,872–53,326,565, 1 gene, copy number 6: AC027329.1.
- chr5:155,491,336–155,493,598, 1 gene, copy number 6: AC008725.1.
- chr7:122,994,704–122,995,700, 1 gene, copy number 5: TAS2R16.
- chr11:21,383,801–21,383,909, 1 gene, copy number 5: RNA5SP337.
- chr11:80,321,620–80,327,911, 1 gene, copy number 5: AP006295.1.
- chr14:21,918,188–21,966,061, 6 genes, copy number 5: TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
